Surgical pathology report (de-identified scan), TCGA case TCGA-EM-A22L, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Health Network, specimen TCGA-EM-A22L-01A (Primary Tumor).

[page 1 of 2]
ICD-0-3
carcinoma, papillary, follicular variant
8340/3
Site: thyroid, NOS C23.9
per 4/26/11

Surgical Pathology Consultation Report

Patient Name:		Accession #:
MRN:		Collected:
DOB:		Received:
Gender: F	Service:	Reported:
HCN:	Visit #:	
Ordering MD:	Location:	
Copy To:	Facility:	

Specimen(s) Received

1. Thyroid: right subtotal hemithyroid stitch upper pole

Diagnosis

Multifocal papillary carcinoma, dominant follicular variant, 2.2 cm: Thyroid
No pathological diagnosis: Lymph node, isthmus
- Right hemithyroidectomy specimen

Synoptic Data

Procedure:	Right hemithyroidectomy
Received:	Fresh
Specimen Integrity:	Intact
Specimen Size:	Right lobe: 3.9 cm 2.3 cm 1.6 cm Isthmus +/- pyramidal lobe: 1.7 cm 1.6 cm 0.7 cm 8.7 g
Specimen Weight:	
Tumor Focality:	Multifocal, ipsilateral
----- DOMINANT TUMOR -----	
Tumor Laterality:	Right lobe
Tumor Size:	Greatest dimension: 2.2cm Additional dimension: 2.1 cm Additional dimension: 1.5 cm
Histologic Type:	Papillary carcinoma, follicular variant per TSS, follicular variant = 100% Papillary carcinoma, macrofollicular variant Follicular architecture Macrofollicular architecture Classical cytomorphology
Histologic Grade:	Not applicable
Margins:	Margins uninvolved by carcinoma
Tumor Capsule:	Partially encapsulated
Tumor Capsular Invasion:	Present, extent minimal
Lymph-Vascular Invasion:	Not identified

Dual/Sync. Primary		

KMI 4/25/11 4/26/11 per

[page 2 of 2]
Perineural Invasion:	Not identified
Extrathyroidal Extension:	Not identified
----- SECOND TUMOR -----	
Tumor Laterality:	Right lobe
Tumor Size:	Greatest dimension: 0.1cm
Histologic Type:	Papillary carcinoma, follicular variant
	Papillary carcinoma, microcarcinoma (occult, small or microscopic) variant
	Follicular architecture
	Classical cytomorphology
Histologic Grade:	Not applicable
Margins:	Margins uninvolved by carcinoma
Tumor Capsule:	None
Tumor Capsular Invasion:	Not identified
Lymph-Vascular Invasion:	Not identified
Perineural Invasion:	Not identified
Extrathyroidal Extension:	Not identified
TNM Descriptors:	m (multiple primary tumors)
Primary Tumor (pT):	pT2: Tumor more than 2 cm, but not more than 4 cm, limited to thyroid
Regional Lymph Nodes (pN):	pN0: No regional lymph node metastasis
	Number of regional lymph nodes examined: 1
	Number of regional lymph nodes involved: 0
Distant Metastasis (pM):	Not applicable
Additional Pathologic Findings:	None Identified

*Pathologic Staging is based on AJCC/UICC TNM, 7th Edition

Comment

The dominant nodule exhibits multifocal transformation to papillary carcinoma and the extent of malignancy warrants classification of the entire nodule as papillary carcinoma. There is also a 0.1cm follicular variant papillary microcarcinoma in the right lobe. The overall morphological features are those of a low risk papillary carcinoma.

Electronically verified

by:

Gross Description

The specimen labeled with the patient's name and as "right subtotal thyroid stitch upper pole", consists of a right hemithyroidectomy specimen that weighs 8.7 g. The lobe measures 3.9 cm SI x 2.3 cm ML x 1.6 cm AP and the isthmus measures 1.7 SI x 1.6cm ML x 0.7cm AP. No parathyroid gland or lymph nodes are identified grossly. The mid superior lobe contains one well delineated nodule that measures 2.1 cm SI x 2.2cm ML x 1.5 cm AP. The cut surface of the nodule has a variegated red-tan color, and has a soft and flabby consistency. Sections of nodule and normal tissue are stored frozen. The remainder of the specimen is submitted as follows:

- 1A-F lobe, superior to inferior
- 1G isthmus

Source: NCI Genomic Data Commons file 8484c278-c5fc-459d-82ff-f885785ea0e3 (TCGA-EM-A22L.D48FB953-758B-4515-B244-09DCACD29441.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).